HCMI case HCM-BROD-0043-C16 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bea4ff97-4e53-434e-b260-81d6aa33106d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1944; Vital status: Dead; Days to death: 847 days (2.3 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C78.2; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Pleura, NOS; Classification of tumor: metastasis; Age at diagnosis: 68.7 years (25,092 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic stage: Stage IV; Tumor grade: G3; Metastasis at diagnosis: No Metastasis; Prior treatment: No.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; Surgery, NOS, for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 817 days (2.2 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 817 days (2.2 years).
- Days to follow up: 847 days (2.3 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 842.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples)
- Sample HCM-BROD-0043-C16-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0043-C16-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen; Passage count: 7.
